CCDI case PBBRKB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/ad98053c-e111-4a29-b8a2-6bb14bf9637c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 3.6 years (1,308 days).

Biospecimens (3 samples)
- Sample 0DF3K2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF3K3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF3K4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
